Somatic mutation profile of tumor specimen TCGA-ED-A7PX-01A (aliquot TCGA-ED-A7PX-01A-51D-A34Z-10) from TCGA case TCGA-ED-A7PX, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 48.3 years (17,638 days).
Specimen TCGA-ED-A7PX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a428e17b-9e83-4219-985a-8bbda6a1a0a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A7PX-10A (Blood Derived Normal), aliquot TCGA-ED-A7PX-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74643fd5-46d9-40de-b8d1-aea6946b5b09

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Frame Shift Ins 3, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA3 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.083); catalogued as rs199567944, COSV57049265; called by muse, varscan2
- AKAP13 | c.2872C>T p.Q958* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV63462968; called by muse, mutect2, varscan2
- APBA1 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1440567010, COSV55227383; called by muse, mutect2, varscan2
- CIBAR2 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV73320645; called by muse, mutect2, varscan2
- CTIF | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.176); catalogued as COSV99838654; called by muse, mutect2, varscan2
- CUL9 | c.4519C>G p.H1507D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV52730821; called by muse, mutect2, varscan2
- DEFB116 | c.107C>G p.P36R | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV68722249; called by muse, mutect2, varscan2
- DRAP1 | c.239T>G p.F80C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100437038, COSV56989003; called by muse, mutect2, varscan2
- ERBB3 | c.3903G>T p.Q1301H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57257189, COSV57265156; called by muse, mutect2, varscan2
- FNIP2 | c.2678C>T p.S893L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs763748801, COSV52441927; called by muse, mutect2, varscan2
- GRIA1 | c.2111T>C p.M704T | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV53611294; called by muse, mutect2, varscan2
- IGDCC4 | c.2613dup p.T872Hfs*22 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs761621429; called by mutect2, varscan2
- KCNS2 | c.216C>A p.D72E | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54639408; called by muse, mutect2, varscan2
- MCM8 | c.483T>A p.H161Q | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV52544349; called by muse, mutect2, varscan2
- NIN | c.5973G>T p.R1991S (on ENST00000382041 / NM_182946.1; = p.R1278S on NM_016350.4) | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV55396695; called by muse, mutect2, varscan2
- OR51V1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs774588813, COSV58315645; called by muse, mutect2, varscan2
- P2RX1 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as COSV56654543; called by muse, mutect2, varscan2
- PRIMA1 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 16/26 reads (62%) | catalogued as COSV100301100, COSV60264291, COSV60265247; called by muse, mutect2, varscan2
- PSD2 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs142293471; called by muse, varscan2
- RADIL | c.316C>A p.Q106K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV68202092; called by muse, mutect2, varscan2
- SRGAP1 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV61900130; called by muse, varscan2
- TBC1D9 | c.3341C>T p.P1114L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs199802386, COSV71307302; called by muse, mutect2, varscan2
- TSC1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53769167, COSV99037022; called by muse, mutect2, varscan2
- ZNF366 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as rs776968247, COSV59216874; called by muse, mutect2, varscan2
- BAP1 | c.2034dup p.I679Yfs*38 | Frame Shift Ins (INS) | VAF 32/72 reads (44%) | called by mutect2, pindel, varscan2
- CREG2 | c.617dup p.N206Kfs*4 | Frame Shift Ins (INS) | VAF 60/189 reads (32%) | called by mutect2, pindel, varscan2
- RBM33 | c.3367C>T p.P1123S | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AKAP13 | c.2871A>T p.G957= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV63462961; called by muse, mutect2, varscan2
- CTIF | c.222C>A p.S74= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV99838658; called by muse, mutect2, varscan2
- HTRA3 | c.1059G>A p.K353= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV56471825; called by muse, mutect2, varscan2
- RNF14 | c.783A>G p.Q261= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs765963956, COSV61662567; called by muse, mutect2, varscan2
- SP110 | c.903A>C p.T301= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as COSV51256814; called by muse, mutect2, varscan2
- ZNF550 | c.66C>G p.T22= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV57306018; called by muse, mutect2, varscan2
- NBPF11 | c.-548-2928C>T | Intron (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
